Gene-level copy-number profile of tumor specimen C3L-00604-01 from CPTAC case C3L-00604, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 61.1 years (22,335 days).
Specimen C3L-00604-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 20e48e3f-f838-461f-ac70-16f4f071dbec.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-00604-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,232 have no estimate.
https://portal.gdc.cancer.gov/files/0bbaedb5-5fc0-478e-9fd1-c2018a01e8d7

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 100; copy number 1: 10,029; copy number 2: 42,061; copy number 3: 5,212; copy number 4: 316; copy number 5: 67; copy number 6: 156; copy number 7: 218; copy number 8: 132; copy number 9: 21; copy number 10: 16; copy number 11: 52; copy number 12: 11.

Homozygous deletions (total copy number 0; autosomes only): 100 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:72,301,472–72,301,829, 1 gene: RPL31P12.
- chr9:19,895,800–19,929,937, 2 genes: AL158077.1, AL591222.1.
- chr9:20,331,446–23,672,387, 71 genes (within-gene range 0–1) (broad region; genes not listed).
- chr9:23,671,788–23,956,444, 6 genes: AL445623.1, NOP56P2, ELAVL2, AL365204.1, AL365204.2, AL365204.3.
- chr9:64,369,394–64,889,063, 18 genes: ANKRD20A4P, RNU6-1193P, SNX18P9, CR769776.2, CYP4F25P, CR769776.1, CNN2P3, GXYLT1P6, AL773524.1, AQP7P2, AL445665.1, BMS1P11, AL359955.2, IGKV1OR-2, BNIP3P4, AL359955.1, AC125634.1, RNU6-1293P.
- chr15:20,344,736–20,359,166, 1 gene: AC026495.1.
- chr21:44,107,373–44,131,181, 1 gene: PWP2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 673 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:2,013,213–3,652,761, 51 genes, copy number 7 (within-gene range 1–7): AL391845.2, GABRD, AL391845.1, PRKCZ, AL590822.2, PRKCZ-AS1, FAAP20, AL590822.1, SKI, AL590822.3, MORN1, AL589739.1, AL513477.1, AL513477.2, RER1, PEX10, PLCH2, AL139246.1, AL139246.4, PANK4, HES5, AL139246.5, TNFRSF14-AS1, TNFRSF14, AL139246.2, AL139246.3, PRXL2B, MMEL1, MMEL1-AS1, TTC34, AC242022.2, AC242022.1, AL592464.2, AL592464.3, AL592464.1, ACTRT2, PRDM16-DT, PRDM16, MIR4251, AL008733.1, AL512383.1, AL590438.1, AL354743.2, AL354743.1, ARHGEF16, AL512413.1, MEGF6, MIR551A, AL513320.1, TPRG1L, WRAP73.
- chr1:24,899,511–25,362,361, 17 genes, copy number 8 (within-gene range 2–8): RUNX3, MIR6731, RUNX3-AS1, AL445471.1, MIR4425, LINC02793, AL050344.1, IFITM3P7, AL031432.1, SYF2, RSRP1, AL031432.3, AL031432.2, RHD, SDHDP6, AL928711.1, TMEM50A.
- chr8:65,377,592–66,432,370, 17 genes, copy number 8 (within-gene range 1–8): PPIAP86, LINC01299, AC100814.1, Y_RNA, ARMC1, MTFR1, AC055822.1, PDE7A, AC100812.1, DNAJC5B, AC084082.1, TRIM55, CRH, LINC00967, AC009879.4, RRS1-AS1, RRS1.
- chr8:95,947,781–106,752,694, 207 genes, copy number 5–7 (broad region; genes not listed).
- chr8:108,871,128–109,975,771, 14 genes, copy number 6: AC104248.1, TRHR, NUDCD1, AC021237.1, ENY2, PKHD1L1, MAPK6P5, EBAG9, SYBU, AC079061.1, AC023245.2, AC023245.1, KCNV1, AC027451.1.
- chr8:112,148,742–112,148,825, 1 gene, copy number 6: RNU4-37P.
- chr8:133,191,039–134,979,279, 37 genes, copy number 5: CCN4, NDRG1, KC877373.1, AF186190.1, ST13P6, ST3GAL1, AC103706.2, AC103706.3, AC103706.1, AC090821.1, Metazoa_SRP, MTND2P7, MTCO1P49, AC133634.1, AC090821.2, AC090821.3, AC110741.1, AC110741.3, AC110741.2, AC105180.2, AC105180.1, ZFAT, AC015599.1, ZFAT-AS1, AC015599.2, AC015599.3, AC087045.1, AC087045.2, AC087045.3, AC083843.3, AC083843.2, MIR30B, MIR30D, AC083843.1, NCRNA00250, AC103764.1, RPL23AP56.
- chr8:139,460,062–145,066,685, 205 genes, copy number 5–12 (broad region; genes not listed).
- chr9:42,566,679–42,569,353, 2 genes, copy number 10: BX088651.4, BX088651.1.
- chr9:66,022,661–66,113,085, 5 genes, copy number 11 (within-gene range 1–11): GXYLT1P4, AL136317.3, AL669942.2, AL669942.1, AL513478.4.
- chr9:66,721,158–66,745,929, 3 genes, copy number 9: ATP5F1AP10, SDR42E1P4, FKBP4P8.
- chr16:30,896,614–31,191,605, 32 genes, copy number 9–10: CTF1, CTF2P, FBXL19-AS1, FBXL19, AC135048.1, ORAI3, AC135048.3, SETD1A, AC135048.4, HSD3B7, STX1B, STX4, AC135050.3, AC135050.1, ZNF668, AC135050.4, ZNF646, PRSS53, AC135050.2, VKORC1, AC135050.7, BCKDK, KAT8, AC135050.5, AC135050.6, AC009088.3, PRSS8, PRSS36, AC009088.4, NDUFA3P6, FUS, AC009088.2.
- chr16:89,490,719–89,638,456, 6 genes, copy number 8: SPG7, AC092123.1, RPL13, SNORD68, CPNE7, DPEP1.
- chr21:13,038,160–15,880,069, 69 genes, copy number 8–12 (broad region; genes not listed).
- chr21:20,597,953–21,686,329, 7 genes, copy number 8: AP001506.1, LINC00320, PPIAP1, NCAM2, AP001136.1, AP001117.1, AF241725.1.

Autosomal genes at a single copy (total copy number 1): 10,029. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
